CGCI case BLGSP-71-29-00541 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/940d905d-b412-47d0-8a9b-531171709cca

Demographics
Sex at birth: male.

Biospecimens (1 sample)
- Sample BLGSP-71-29-00541-50A: Sample type: Cell Lines; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Derived Cell Line; Preservation method: Frozen.
